FM case AD7670 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/51dfb863-cbb3-4425-b3b6-46d3bed38a3f

Male, 58.5 years: Acinar adenocarcinoma (ICD-O-3 8550/3) of the prostate gland; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
